Surgical pathology report (de-identified scan), TCGA case TCGA-22-5491, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5491-01A (Primary Tumor).

TCGA-22-5491

DIAGNOSIS:

Lung, left lower lobe, lobectomy: Invasive grade 3 (of 4) squamous cell carcinoma, forming a solid mass measuring 2 x 1.2 x 1.2 cm, located 0.8 cm from the bronchial margin which is histologically negative. Multiple (4) intrapulmonary peribronchial lymph nodes are negative for tumor. A hyalinized granuloma is identified in one of the lymph nodes. The remaining lung parenchyma shows organizing pneumonia

Lymph nodes, superior and inferior mediastina, aortic, N1, excision:

Multiple (4 right lower paratracheal, 3 left lower paratracheal, 2 aortopulmonary, 2 anterior mediastinal, 8 subcarinal, 4 inferior pulmonary ligament, 3 interlobar) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file cf587607-efc9-4720-91ea-3548802ed749 (TCGA-22-5491.187AB883-E568-47DB-A048-C39C4E9D0F29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).